TARGET case TARGET-15-SJMPAL040035 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/453d4220-95cd-437d-82d3-e4f1209cfea8

Demographics
Sex at birth: male; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 0.9 years (334 days); Year of diagnosis: 2009; Days to last follow up: 1,975 days (5.4 years).

Follow-up (1 entry)
- Days to follow up: 1,975 days (5.4 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,975; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 394 ×10³/µL.

Biospecimens (4 samples)
- Samples TARGET-15-SJMPAL040035-03A, TARGET-15-SJMPAL040035-03A.1, TARGET-15-SJMPAL040035-03A.2 (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-15-SJMPAL040035-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 1975
- Protocol: Singapore
- WBC at Diagnosis: 394
- Initial Therapy: hybrid
- Karyotype: 46,XY,ins(11;9)(q23;p?22p?24)[19]/46,XY[1]
- WHO ALAL Classification: MLL
- WHO Dx: MLL
